Gene-level copy-number profile of tumor specimen TCGA-KP-A3W0-01A from TCGA case TCGA-KP-A3W0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.2 years (26,378 days).
Specimen TCGA-KP-A3W0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.72b4b9c4-5386-4fa6-b267-22418140cff9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KP-A3W0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e16ab9f-ae25-4995-aa89-3608d9fcef01

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,262; copy number 2: 37,820; copy number 3: 5,821; copy number 4: 1,554; copy number 5: 601; copy number 6: 89; copy number 7: 547; copy number 8: 73; copy number 10: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KP-A3W0-01A-21D-A227-01): tumor purity 0.7, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,362 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,272,932–198,222,513, 457 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:10,901,978–10,940,735, 3 genes, copy number 6: Y_RNA, NDUFA4, AC007029.1.
- chr7:11,006,399–11,006,876, 1 gene, copy number 6: RPL23AP52.
- chr7:11,820,317–14,071,380, 23 genes, copy number 6: THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21.
- chr7:14,190,795–14,192,157, 1 gene, copy number 6: EEF1A1P26.
- chr7:151,238,764–151,277,896, 1 gene, copy number 6 (within-gene range 3–6): SMARCD3.
- chr7:151,249,325–151,378,449, 2 genes, copy number 6 (within-gene range 3–6): AC005486.1, NUB1.
- chr8:37,405,439–58,272,450, 361 genes, copy number 7–10 (broad region; genes not listed).
- chr19:16,574,907–16,660,115, 2 genes, copy number 7 (within-gene range 1–7): MED26, AC008764.4.
- chr19:16,610,374–24,163,425, 373 genes, copy number 5–7 (broad region; genes not listed).
- chr21:13,349,265–21,797,415, 138 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,262. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
